Somatic mutation profile of tumor specimen C3L-03735-01 (aliquot CPT0264120006) from CPTAC case C3L-03735, project CPTAC-3 (Brain — Gliomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 74.1 years (27,073 days).
Specimen C3L-03735-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 805c4d19-b4b5-40ce-a13d-b4b533676361.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-03735-32 (Blood Derived Normal), aliquot CPT0265770002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a6e7d8b9-db3e-408e-af35-2eb4db216d36

The open-access MAF lists 79 somatic variants for this specimen: 59 protein-altering or splice-affecting, 13 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 41, Silent 13, Nonsense Mutation 8, Frame Shift Del 3, Frame Shift Ins 3, Intron 3, Splice Site 2, 3'UTR 2, In Frame Ins 1, RNA 1, 3'Flank 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.809T>G p.F270C | Missense Mutation (SNP) | VAF 515/629 reads (82%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519986, COSV52661272, COSV52676663, COSV52688116; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ZEB2 | c.3164A>G p.Y1055C | Missense Mutation (SNP) | VAF 199/504 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1135402759, CM135848, COSV57966100; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCA8 | c.1000G>A p.V334M | Missense Mutation (SNP) | VAF 59/143 reads (41%) | SIFT tolerated (0.09); PolyPhen benign (0.149); catalogued as rs138246161; called by muse, mutect2, varscan2
- CFAP46 | c.6598G>A p.V2200M | Missense Mutation (SNP) | VAF 89/238 reads (37%) | SIFT tolerated (0.26); PolyPhen benign (0.047); catalogued as rs745386201; called by muse, mutect2, varscan2
- CFTR | c.3136G>T p.E1046* | Nonsense Mutation (SNP) | VAF 99/255 reads (39%) | catalogued as CM1212242; called by muse, mutect2, varscan2
- CSF2RB | c.1412G>A p.R471H | Missense Mutation (SNP) | VAF 182/449 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.097); catalogued as rs573228861, COSV99453107; called by muse, mutect2, varscan2
- CWC25 | c.187G>A p.V63I | Missense Mutation (SNP) | VAF 33/74 reads (45%) | SIFT tolerated (0.19); PolyPhen benign (0.015); catalogued as rs555146635; called by muse, mutect2, varscan2
- GLB1L2 | c.505G>A p.E169K | Missense Mutation (SNP) | VAF 75/198 reads (38%) | SIFT tolerated (0.63); PolyPhen benign (0.006); catalogued as rs544313782, COSV60277940; called by muse, mutect2, varscan2
- ITGB5 | c.584C>T p.P195L | Missense Mutation (SNP) | VAF 51/145 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs137996041, COSV56147725, COSV56150943; called by muse, mutect2, varscan2
- KMT5B | c.1592G>A p.S531N | Missense Mutation (SNP) | VAF 23/269 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.038); catalogued as rs766136425; called by muse, mutect2
- OR13H1 | c.713C>A p.T238N | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.186); catalogued as rs780080763; called by muse, mutect2, varscan2
- OSMR | c.131C>T p.T44M | Missense Mutation (SNP) | VAF 21/200 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.197); catalogued as rs372089425; called by muse, mutect2
- PCDHGA10 | c.617G>A p.R206H | Missense Mutation (SNP) | VAF 14/300 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV99541924; called by muse, mutect2
- PKD1 | c.8790C>T p.D2930= | Splice Region (SNP) | VAF 264/641 reads (41%) | catalogued as rs750206486; called by muse, mutect2, varscan2
- POTEE | c.238G>A p.V80M | Missense Mutation (SNP) | VAF 251/684 reads (37%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.111); catalogued as rs370032960; called by muse, mutect2, varscan2
- PPM1D | c.1547C>A p.S516* | Nonsense Mutation (SNP) | VAF 167/445 reads (38%) | catalogued as rs772936724, COSV59955538, COSV59956876; called by muse, mutect2, varscan2
- SI | c.4927-1G>A p.X1643_splice | Splice Site (SNP) | VAF 122/349 reads (35%) | catalogued as rs779508795; called by muse, mutect2, varscan2
- SIX5 | c.928G>A p.G310S | Missense Mutation (SNP) | VAF 60/150 reads (40%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs766898643, COSV52182087; called by muse, mutect2, varscan2
- TAS2R31 | c.635A>G p.H212R | Missense Mutation (SNP) | VAF 87/257 reads (34%) | SIFT tolerated (0.12); PolyPhen benign (0.049); catalogued as rs569826674; called by muse, mutect2, varscan2
- TBC1D17 | c.371G>A p.G124E | Missense Mutation (SNP) | VAF 126/348 reads (36%) | SIFT tolerated (0.57); PolyPhen benign (0.127); catalogued as COSV55578478; called by muse, mutect2
- TKFC | c.1118G>A p.R373Q | Missense Mutation (SNP) | VAF 89/230 reads (39%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as rs148178060, COSV99582247; called by muse, mutect2, varscan2
- UNKL | c.1828G>A p.E610K | Missense Mutation (SNP) | VAF 109/246 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs1273334444; called by muse, mutect2, varscan2
- AMMECR1L | c.28C>A p.L10I | Missense Mutation (SNP) | VAF 14/498 reads (3%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.017); called by muse, mutect2
- ARHGAP29 | c.1143+1G>A p.X381_splice | Splice Site (SNP) | VAF 51/153 reads (33%) | called by mutect2, varscan2
- BMP2K | c.750G>A p.W250* | Nonsense Mutation (SNP) | VAF 51/138 reads (37%) | called by muse, mutect2, varscan2
- CD38 | c.272dup p.A92Cfs*12 | Frame Shift Ins (INS) | VAF 75/206 reads (36%) | called by mutect2, pindel, varscan2
- CDK8 | c.871T>C p.C291R | Missense Mutation (SNP) | VAF 52/160 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.616); called by muse, mutect2, varscan2
- COL4A1 | c.3257G>A p.S1086N | Missense Mutation (SNP) | VAF 235/653 reads (36%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.774); called by muse, mutect2, varscan2
- CROCC2 | c.3674T>C p.L1225P | Missense Mutation (SNP) | VAF 71/179 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- DDO | c.400C>T p.Q134* | Nonsense Mutation (SNP) | VAF 95/259 reads (37%) | called by muse, mutect2, varscan2
- DGKZ | c.954G>C p.K318N (on ENST00000454345 / NM_001105540.2; = p.K130N on NM_003646.4) | Missense Mutation (SNP) | VAF 112/356 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); called by muse, mutect2, varscan2
- DHX36 | c.2273C>G p.T758R | Missense Mutation (SNP) | VAF 54/158 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.889); called by muse, mutect2, varscan2
- EPHA4 | c.1943T>A p.I648N | Missense Mutation (SNP) | VAF 95/223 reads (43%) | SIFT tolerated (0.15); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ERI2 | c.1881C>G p.Y627* | Nonsense Mutation (SNP) | VAF 84/192 reads (44%) | called by muse, mutect2, varscan2
- IFIT5 | c.1256C>G p.A419G | Missense Mutation (SNP) | VAF 54/185 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- INTS11 | c.800del p.F267Sfs*5 | Frame Shift Del (DEL) | VAF 29/92 reads (32%) | called by mutect2, pindel, varscan2
- MYO6 | c.1057G>T p.E353* | Nonsense Mutation (SNP) | VAF 97/239 reads (41%) | called by muse, mutect2, varscan2
- NEMF | c.2419G>T p.D807Y | Missense Mutation (SNP) | VAF 55/159 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.119); called by muse, mutect2, varscan2
- NOTCH1 | c.1607_1609dup p.P536_C537insS | In Frame Ins (INS) | VAF 166/539 reads (31%) | called by mutect2, pindel, varscan2
- NUDT9 | c.256G>A p.G86S | Missense Mutation (SNP) | VAF 140/340 reads (41%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR6C76 | c.487C>G p.L163V | Missense Mutation (SNP) | VAF 71/201 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.907); called by muse, mutect2, varscan2
- PAPSS1 | c.383T>C p.I128T | Missense Mutation (SNP) | VAF 108/250 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.31); called by muse, mutect2, varscan2
- PCDHB5 | c.1512dup p.I505Hfs*90 | Frame Shift Ins (INS) | VAF 321/944 reads (34%) | called by mutect2, pindel, varscan2
- PCDHGB1 | c.604C>T p.Q202* | Nonsense Mutation (SNP) | VAF 64/161 reads (40%) | called by muse, mutect2, varscan2
- PKD1 | c.9460C>G p.L3154V | Missense Mutation (SNP) | VAF 188/550 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- POU3F3 | c.620C>G p.P207R | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.02); called by muse, mutect2
- PTPRZ1 | c.6327G>T p.M2109I | Missense Mutation (SNP) | VAF 64/190 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); called by muse, mutect2, varscan2
- SEC22A | c.730T>G p.L244V | Missense Mutation (SNP) | VAF 88/229 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- SETD2 | c.2756del p.E919Gfs*3 | Frame Shift Del (DEL) | VAF 160/235 reads (68%) | called by mutect2, pindel, varscan2
- SLC9C1 | c.118C>T p.P40S | Missense Mutation (SNP) | VAF 101/242 reads (42%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.848); called by muse, mutect2, varscan2
- SPATS2L | c.121G>A p.D41N | Missense Mutation (SNP) | VAF 39/138 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.669); called by muse, mutect2, varscan2
- STAMBPL1 | c.682G>C p.D228H | Missense Mutation (SNP) | VAF 73/193 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.372); called by muse, mutect2, varscan2
- TAAR9 | c.726del p.E243Rfs*7 | Frame Shift Del (DEL) | VAF 5/13 reads (38%) | called by mutect2, varscan2
- TENM3 | c.1473G>A p.W491* | Nonsense Mutation (SNP) | VAF 163/466 reads (35%) | called by muse, mutect2, varscan2
- TUBB8B | c.895A>G p.M299V | Missense Mutation (SNP) | VAF 24/428 reads (6%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.897); called by muse, mutect2
- VWCE | c.1865G>A p.C622Y | Missense Mutation (SNP) | VAF 112/307 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- WASHC5 | c.1294C>G p.L432V | Missense Mutation (SNP) | VAF 21/439 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); called by muse, mutect2
- WDR43 | c.443A>G p.K148R | Missense Mutation (SNP) | VAF 37/115 reads (32%) | SIFT tolerated (0.4); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- ZEB2 | c.1952dup p.Y652Ifs*22 | Frame Shift Ins (INS) | VAF 65/191 reads (34%) | called by mutect2, pindel, varscan2
- ACE | c.1362G>A p.L454= | Silent (SNP) | VAF 158/415 reads (38%) | called by muse, mutect2, varscan2
- AIRE | c.568A>C p.R190= | Silent (SNP) | VAF 99/291 reads (34%) | called by muse, mutect2, varscan2
- ARHGEF10 | c.99C>T p.P33= (on ENST00000398564; = p.P9= on NM_014629.4) | Silent (SNP) | VAF 161/397 reads (41%) | catalogued as rs374914801; called by muse, mutect2, varscan2
- ARID2 | c.903C>T p.G301= | Silent (SNP) | VAF 81/282 reads (29%) | catalogued as COSV57617669; called by muse, mutect2, varscan2
- CARMIL2 | c.3399C>T p.G1133= | Silent (SNP) | VAF 84/190 reads (44%) | catalogued as rs375307002, COSV54666296; called by muse, mutect2, varscan2
- CDKAL1 | c.21T>C p.D7= | Silent (SNP) | VAF 63/134 reads (47%) | called by mutect2, varscan2
- CYP2S1 | c.1398G>A p.P466= | Silent (SNP) | VAF 273/678 reads (40%) | catalogued as rs753564032, COSV59505069; called by muse, mutect2, varscan2
- GK2 | c.165A>G p.Q55= | Silent (SNP) | VAF 65/162 reads (40%) | called by muse, mutect2, varscan2
- KALRN | c.2742C>T p.N914= | Silent (SNP) | VAF 99/244 reads (41%) | catalogued as rs997627875, COSV99564838; called by muse, mutect2, varscan2
- KLK13 | c.351C>G p.T117= | Silent (SNP) | VAF 8/230 reads (3%) | called by muse, mutect2
- NKX2-4 | c.1005C>T p.A335= | Silent (SNP) | VAF 17/24 reads (71%) | called by muse, mutect2, varscan2
- RRM2B | c.651C>G p.L217= | Silent (SNP) | VAF 112/350 reads (32%) | called by muse, varscan2
- SALL1 | c.1987T>C p.L663= | Silent (SNP) | VAF 86/198 reads (43%) | called by muse, mutect2, varscan2
- ABCC9 | chr12:21801132 C>T | 3'Flank (SNP) | VAF 14/363 reads (4%) | catalogued as rs1477972160, COSV53964422; called by muse, mutect2
- CTAGE1 | c.*922G>A | 3'UTR (SNP) | VAF 40/94 reads (43%) | called by muse, mutect2
- EYS | c.1767-8015T>C | Intron (SNP) | VAF 28/88 reads (32%) | catalogued as rs1172966390; called by mutect2, varscan2
- GRIN1 | c.1114-9C>T | Intron (SNP) | VAF 164/381 reads (43%) | called by muse, mutect2, varscan2
- PAOX | c.*33G>A | 3'UTR (SNP) | VAF 32/62 reads (52%) | catalogued as rs766737032; called by muse, mutect2, varscan2
- PLAU | c.58-13G>A | Intron (SNP) | VAF 54/122 reads (44%) | catalogued as rs369662596; called by muse, mutect2, varscan2
- ZNF503-AS2 | n.453G>A | RNA (SNP) | VAF 35/386 reads (9%) | called by muse, mutect2
